Somatic mutation profile of tumor specimen 0DVJON from CCDI case PBCMLA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Cerebrum; Age at diagnosis: 3.4 years (1,258 days).
Specimen 0DVJON: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 620f6d31-cf05-4040-b70f-9f9e9f3acec6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1073e3da-668d-4973-8fed-7511018a42f4

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 10, Silent 9, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INTS1 | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1009068667, COSV67180158; called by muse, mutect2
- KIAA1210 | c.3572G>A p.R1191H | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs561471717, COSV68178067; called by muse, mutect2, varscan2
- NYAP2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 247/1208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754105472, COSV56007997; called by muse, mutect2, varscan2
- STEAP3 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 67/988 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as rs759879690, COSV61529700; called by muse, mutect2
- ACADVL | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 50/604 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2
- BTBD7 | c.1371+1G>C p.X457_splice | Splice Site (SNP) | VAF 63/328 reads (19%) | called by muse, mutect2
- DMD | c.3394A>C p.K1132Q | Missense Mutation (SNP) | VAF 48/838 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.025); called by muse, mutect2
- DPH1 | c.1016A>C p.Q339P | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KLF8 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 41/465 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- MAB21L2 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- RNF39 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- C16orf71 | c.891C>T p.R297= | Silent (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2, varscan2
- CHRNA9 | c.1434G>A p.A478= | Silent (SNP) | VAF 27/440 reads (6%) | catalogued as rs771890826; called by muse, mutect2
- HCN2 | c.1821C>T p.F607= | Silent (SNP) | VAF 14/286 reads (5%) | catalogued as rs1410521098; called by muse, mutect2
- HMGB3 | c.117G>A p.A39= | Silent (SNP) | VAF 80/618 reads (13%) | catalogued as COSV57486013; called by muse, mutect2, varscan2
- KATNIP | c.4011C>T p.C1337= | Silent (SNP) | VAF 114/324 reads (35%) | catalogued as rs750590554, COSV55176020; called by muse, mutect2, varscan2
- MRTFA | c.645C>T p.F215= | Silent (SNP) | VAF 26/328 reads (8%) | catalogued as rs1203901499; called by muse, mutect2
- RPH3AL | c.912C>T p.D304= | Silent (SNP) | VAF 42/482 reads (9%) | catalogued as rs374756503; called by muse, mutect2
- ZFPM2 | c.3177G>A p.Q1059= | Silent (SNP) | VAF 111/568 reads (20%) | catalogued as COSV65872635; called by muse, mutect2, varscan2
- ZMYM3 | c.1125C>A p.G375= | Silent (SNP) | VAF 54/324 reads (17%) | called by mutect2, varscan2
